Somatic mutation profile of tumor specimen TCGA-ZM-AA0N-01A (aliquot TCGA-ZM-AA0N-01A-21D-A435-10) from TCGA case TCGA-ZM-AA0N, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IB; Age at diagnosis: 44.1 years (16,094 days).
Specimen TCGA-ZM-AA0N-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 346721a3-43b9-4c21-82f2-741628328a3a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZM-AA0N-10A (Blood Derived Normal), aliquot TCGA-ZM-AA0N-10A-01D-A438-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1e8b02db-bf54-43b1-b768-93143aebf118

The open-access MAF lists 19 somatic variants for this specimen: 13 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 5, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EPS8L3 | c.864C>A p.F288L | Missense Mutation (SNP) | VAF 26/157 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs749961059; called by muse, mutect2, varscan2
- GABRG2 | c.565G>A p.E189K | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV62718083; called by muse, mutect2, varscan2
- HSH2D | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.804); catalogued as rs1181414596; called by muse, mutect2, varscan2
- PRG4 | c.1874C>T p.T625M | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.381); catalogued as rs767060959; called by muse, mutect2, varscan2
- USP19 | c.3806G>A p.G1269E | Missense Mutation (SNP) | VAF 21/135 reads (16%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.095); catalogued as rs1559981812; called by muse, mutect2, varscan2
- ACER3 | c.556T>C p.F186L | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ADAM22 | c.1655G>C p.R552T | Missense Mutation (SNP) | VAF 7/108 reads (6%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.651); called by muse, mutect2
- BEND3 | c.2432G>A p.R811H | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DENND6A | c.1019C>G p.T340S | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- DHDH | c.496G>C p.D166H | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- EMID1 | c.1249C>A p.P417T | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- FAM83B | c.2998A>G p.M1000V | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GDAP1 | c.397A>T p.M133L | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- ARL2 | c.294C>T p.R98= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as rs779177133; called by muse, mutect2, varscan2
- CFAP46 | c.5835C>T p.S1945= | Silent (SNP) | VAF 12/101 reads (12%) | catalogued as rs368842765; called by muse, mutect2, varscan2
- GRM5 | c.1254C>T p.L418= | Silent (SNP) | VAF 17/105 reads (16%) | called by muse, mutect2, varscan2
- SLC18A1 | c.1296C>T p.I432= | Silent (SNP) | VAF 12/172 reads (7%) | catalogued as rs778807328, COSV52347932; called by muse, mutect2
- TTYH1 | c.949C>T p.L317= | Silent (SNP) | VAF 5/64 reads (8%) | catalogued as rs199946983; called by muse, mutect2
- CFP | c.227+55G>C | Intron (SNP) | VAF 5/24 reads (21%) | called by muse, mutect2
